Surgical pathology report (de-identified scan), TCGA case TCGA-43-8118, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-8118-01A (Primary Tumor).

[page 1 of 4]
Final Surgical Pathology Report

Procedure:

Diagnosis

- A. 4L, biopsy: Benign lymphoid tissue with anthracosis
- B. 2R, biopsy: Benign lymphoid tissue with anthracosis
- C. Level 1, biopsy: Benign adipose tissue with 4 mm fragment of parathyroid gland
- D. Level 7, biopsy: Benign lymphoid tissue with anthracosis
- E. 4R, biopsy: Benign lymphoid tissue with anthracosis
- F. Piece of right upper lobe, biopsy: Benign lung tissue with single calcified hyalinized granuloma. No definite fungal organisms present
- G. Lateral 12, biopsy: Benign lymphoid tissue with anthracosis
- H. Posterior margin 4th rib, biopsy: Portions of bone with trilineage marrow, negative for tumor
- I. Margin 3rd rib, biopsy: Portion of bone negative for tumor
- J. Level 11, biopsy: Benign lymphoid tissue with anthracosis
- K. Level 10, biopsy: Benign lymphoid tissue with anthracosis
- L. Right upper lobe, lobectomy: Lobe of lung with 2 distinct carcinomas. The smaller (pT1b) is a squamous cell carcinoma confined to the parenchyma with negative pleura and margins of resection. The larger tumor (pT2b) is a moderately differentiated adenocarcinoma which spares the pleura but is identified at the parenchymal margin once the staple line was trimmed away. Multiple calcified hyalinized granulomata also present. 4 additional lymph nodes negative for metastatic disease. Marked fibro-inflammatory reaction beyond the tumor and adherent to 2 ribs.
- M. AVF node, biopsy: Benign lung tissue with single calcified hyalinized granuloma.
- N. 4R, biopsy: Benign lymphoid tissue with anthracosis
- O. Level 9, biopsy: Benign lymphoid tissue with anthracosis
- P. level 7, biopsy: Benign lymphoid tissue with anthracosis.

Microscopic Description:

Microscopic examination performed. All lymphoid tissue submitted is negative for metastatic disease but discloses significant anthracosis. Scattered hyalinized and calcified granulomata are noted in parts F., L. and M which on H&E stain suggested the possibility of fungal organisms. However, GMS stain for fungus was performed on part F., blocks L 9-11 and M and were all negative. No definite fungal organisms, therefore, are identified. The stain for acid-fast bacilli these blocks is negative.

[page 2 of 4]
The right upper lobe specimen, part L, discloses two separate carcinomas. The smaller one (2.5 cm) is a squamous cell carcinoma with involvement of a nearby bronchus which also contains squamous cell carcinoma in situ. This tumor has focal keratinization and necrosis, sparing the pleura 1.5 cm away from this tumor is a 6.5 cm cavitating moderately differentiated adenocarcinoma. There is no apparent communication or commingling of these tumor types. The periphery of the invasive adenocarcinoma discloses bronchoalveolar architecture. The 2 densely adherent ribs overlie the vicinity of the adenocarcinoma.

The adenocarcinoma appears confined to the pulmonary parenchyma. Distal to the adenocarcinoma there is a marked fibro-inflammatory response (containing occasional giant cells) which replaces the pleura and extends to the surface of the ribs. There is no actual tumor in this thick fibro-inflammatory layer and the ribs are negative for tumor. Bronchial and vascular margins of resection are negative for tumor. However, the staple line was trimmed away and the remaining parenchymal surface painted with ink. Bronchoalveolar type carcinoma extends to this ink. Please see the template below with each tumor be considered separately. The 1st template pertains to the smaller, squamous cell cancer; the 2nd template the os with the larger, adenocarcinoma.

Histologic type: Squamous cell carcinoma
Histologic grade: Moderately differentiated
Primary tumor (pT): pT1b
Margins of resection: Negative
Direct extension of tumor: Negative
Venous (large vessel) invasion: Negative
Arterial (large vessel) invasion: Negative
Lymphatic (small vessel) invasion: Negative
Regional lymph nodes (pN): Negative, as per parts A., B., D., E., G., J., K., 4 additional nodes from part L., N., O. and P, pN0
Distant metastasis (pM): Cannot be assessed
Other findings: A 2nd malignancy is present, see below.

Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated
Primary tumor (pT): pT2b
Margins of resection: Adenocarcinoma present at margin once staple line is trimmed away
Direct extension of tumor: Negative
Venous (large vessel) invasion: Negative
Arterial (large vessel) invasion: Negative
Lymphatic (small vessel) invasion: Negative
Regional lymph nodes (pN): pN0
Distant metastasis (pM): [Cannot be assessed
Other findings: Multiple calcified, hyalinized granulomata present
Marked fibroinflammatory response distal to the tumor and extending to 2 densely adherent ribs which are otherwise negative for tumor.

Specimen
A .4L
B. 2R
C. Level 1
D. Level 7
E. 4R
F. Piece of RUL - granuloma versus malignancy
G. Level 12
H. Posterior margin fourth rib
I. Margin third rib
J. Level 11
K. Level 10
L. Right upper lobe
M. AFV node
N. 4 R

[page 3 of 4]
O. Level 9
P. Level 7

Clinical Information
Squamous cell lung cancer

Intraoperative Consultation

A - Frozen section and touch preparation disclose benign lymphoid material with anthracosis.
B - Benign lymphoid tissue with anthracosis.
D - Benign lymphoid tissue with anthracosis.
E - Benign lymphoid tissue with anthracosis.
F - Hyalinized nodule with necrosis, favor granuloma. Submitting tissue for cultures recommended.

Gross Description

A. The specimen is received fresh for frozen section labeled "4L". It consists of 3 fragments of soft red black tissue measuring 5 x 4 x 3 mm in aggregate. A touch preparation is made and the entire specimen is submitted for frozen section
B. The specimen is received fresh for frozen section labeled "2R". It consists of a fragment of soft reddish black tissue measuring 4 x 3 x 2 mm. All submitted for frozen section.
C. The specimen is received fresh labeled "level I". It consists of 2 fragments of soft yellow adipose each measuring 1.1 x 0.5 x 0.3 cm. AS1
D. The specimen is received fresh for frozen section labeled "level 7". It consists of 3 fragments of soft reddish black tissue each measuring 4 mm in greatest dimension. All submitted for frozen section
E. The specimen is received fresh for frozen section labeled "4R". It consists of a fragment of soft reddish black tissue measuring 7 x 4 x 3 mm. All submitted for frozen section.
F. Received fresh in a container labeled "piece of right upper lobe" is a portion of tan-pink to gray lung tissue with staples present. It measures 2.6 x 1.5 x 0.4 cm. The staples are removed. The specimen is generally spongy and tan-pink with a firmer 0.2 cm nodule visible from the surface. The specimen is entirely submitted for frozen section in one block.
G. Received fresh and subsequently fixed in formalin labeled "node level 12" is 0.4 x 0.4 x 0.3 cm black tan irregular soft tissue fragment which is entirely submitted in one cassette. AS-1.
H. Received fresh and subsequently fixed in formalin labeled "posterior margin fourth rib" are 2 pink-tan bony irregular tissue fragments which average 2.0 x 1.2 x 0.7 cm. No discrete orientation of the specimens are given. The specimens are sectioned and are entirely submitted in one cassette following decalcification. AS1.
I. Received fresh and subsequently fixed in formalin labeled "margin third rib" is a 1.2 x 1.0 x 0.5 cm pink-tan irregular rubbery to bony tissue fragment which is entirely submitted in one cassette following decalcification. AS1.
J. Received fresh and subsequently fixed in formalin labeled "level 11" are 2 black red irregular soft tissue fragments which average 0.7 cm in greatest dimension. The specimens are entirely submitted in one cassette. AS1.
K. Received fresh and subsequently fixed in formalin labeled "level 10" is a 0.7 x 0.3 x 0.3 cm black irregular soft tissue fragment which is entirely submitted in one cassette. AS1.
L. Received fresh and subsequently fixed in formalin labeled "right upper lobe" is a 196 g, 12.0 x 10.0 x 4.7 cm portion of lung which has 2 segments of rib attached. The longer portion of rib is 7.5 cm and the shorter portion of rib is 5.5 cm. The pleura of the lung is violaceous and rubbery with black stippling diffusely. The specimen has a hilum which is markedly stapled. The specimen is sectioned to show a black tan irregular and cavitating lesion is subjacent to the ribs measuring

[page 4 of 4]
6.5 x 5.5 x 2.8 cm. This may grossly involve the pleura and adherent to the ribs but does not grossly involve the ribs on cut surface. Also grossly identified in the apex of the specimen is an additional black tan lesion which is 2.5 cm in greatest dimension. This comes within 1.5 cm of the first described lesion. The first described lesion comes within 3.5 cm of the bronchial margin and the second described lesion comes within 3.5 cm of the bronchial margin. Both lesions come within 1.5 cm of a surgical staple line. Few hilar nodes are grossly identified. The remainder of the parenchyma is red-brown and spongy. Representative sections of the specimen are submitted as follows: 1 - possible hilar nodes, 2 - vascular and bronchial margin, 3 - 4 - representative section of tumor at apex to pleural surface, 5 - section of surgical staple line, 6 - adjacent rib tumor to normal, 7 - representative section of normal between 2 lesions,, 8 - larger tumor to pleura, 9 - larger tumor to shorter segment of rib following decalcification, 10 through 12 - larger tumor to longer segment of rib following decalcification, RR1 - larger tumor to inked pleura. RS 13. M. Received fresh and subsequently fixed in formalin labeled "AFV node" is a 1.6 x 0.7 x 0.3 cm pink-red irregular soft tissue fragment which is entirely submitted in one cassette. AS-1. N. Received fresh and subsequently fixed in formalin labeled " 4R " is 0.6 x 0.3 x 0.3 cm pink black irregular soft tissue fragment which is entirely submitted in one cassette. AS-1. O. Received fresh and subsequently fixed in formalin labeled "level 9" is a 0.7 x 0.3 x 0.3 cm black tan irregular soft tissue fragment which is entirely submitted in one cassette. AS1. P.. Received fresh and subsequently fixed in formalin labeled "level 7" are multiple black red irregular soft tissue fragments which have an aggregate measurement of 2.0 x 1.5 x 0.3 cm. The specimens are entirely submitted one cassette. AS-1.

Source: NCI Genomic Data Commons file 908fd9f2-9254-47ce-ba3a-2eb51a44ee5d (TCGA-43-8118.52C7F12F-DA4C-4784-9B71-9EB385F25077.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).